Somatic mutation profile of tumor specimen MP2PRT-PAUEKN-TMP1-A (aliquot MP2PRT-PAUEKN-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUEKN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (990 days).
Specimen MP2PRT-PAUEKN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b64759fb-6a59-4704-9389-8ac7cad2b9d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUEKN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUEKN-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9fbfd1eb-b7da-4805-9ba0-da4ac86b532e

The open-access MAF lists 13 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 6, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 47/261 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDH10 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1299821656, COSV52574699, COSV52578909; called by muse, mutect2, varscan2
- CREBBP | c.4424C>G p.P1475R | Missense Mutation (SNP) | VAF 100/285 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52119252, COSV52122229; called by muse, mutect2, varscan2
- OR4C13 | c.338T>G p.L113R | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV73648974; called by muse, mutect2, varscan2
- DDX60L | c.3371G>A p.G1124E | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PMFBP1 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, varscan2
- BICC1 | c.891C>A p.L297= | Silent (SNP) | VAF 132/327 reads (40%) | called by muse, mutect2, varscan2
- IFITM10 | c.648C>T p.L216= | Silent (SNP) | VAF 140/387 reads (36%) | catalogued as rs558406910; called by muse, mutect2, varscan2
- MACF1 | c.4356C>T p.S1452= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as rs372205121; called by muse, mutect2, varscan2
- NDUFA13 | c.432G>A p.T144= | Silent (SNP) | VAF 78/194 reads (40%) | called by muse, mutect2, varscan2
- UNC5A | c.2388G>A p.K796= | Silent (SNP) | VAF 83/234 reads (35%) | called by muse, mutect2, varscan2
- ZNF598 | c.360G>A p.P120= | Silent (SNP) | VAF 43/353 reads (12%) | catalogued as rs749623305; called by muse, mutect2, varscan2
- RABEP1 | c.-191A>G | 5'UTR (SNP) | VAF 46/588 reads (8%) | catalogued as rs954193529; called by muse, mutect2
